Gene-level copy-number profile of tumor specimen MP2PRT-PAVHMV-TMP1-A from MP2PRT case MP2PRT-PAVHMV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,355 days).
Specimen MP2PRT-PAVHMV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e368aebe-dbf5-448f-87cc-b134fb6ef5ff.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAVHMV-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/4aea9559-c38b-42a8-aea5-878e68aa9db8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 209; copy number 1: 51; copy number 2: 44,999; copy number 3: 13,000; copy number 4: 78; copy number 6: 48.

Homozygous deletions (total copy number 0; autosomes only): 209 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,254,015, 40 genes (within-gene range 0–2): IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr7:38,239,580–38,340,998, 16 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–1): AL772307.1.
- chr9:40,105,822–40,153,147, 4 genes: AL773545.3, CDRT15P14, AL773545.1, AL773545.2.
- chr14:105,672,308–106,637,973, 143 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–2): IGHV3-64, IGHV3-65, IGHVII-65-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 48 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,052,514–22,482,959, 47 genes, copy number 6 (within-gene range 1–7): TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
